Surgical pathology report (de-identified scan), TCGA case TCGA-RT-A6YA, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Cleveland Clinic Foundation, specimen TCGA-RT-A6YA-01A (Primary Tumor).

[page 1 of 2]
Results

Patient Info

Patient Name

Sex

DOB

Results

Specimen #:

Submitting Physician:

FINAL DIAGNOSIS

1. Left adrenal gland, laparoscopic adrenalectomy (A) - Pheochromocytoma (15.0 cm in greatest dimension).
- The inked surgical margin of resection is negative for tumor. (See comment)
2. Left peri-adrenal soft tissue, excision (B) - Pheochromocytoma invading large vein wall.
- Fibroadipose tissue negative for tumor. (See comment)

COMMENT

1. The tumor shows capsular invasion as well as involvement of the peri-adrenal soft tissue. Nuclear pleomorphism is identified. Vascular invasion is present (part B). Mitoses are up to 4 per 10 high-power fields. The Pheochromocytoma of the Adrenal gland Scaled Score (PASS) for the tumor is 7. Tumors with a PASS 4 have an increased propensity to behave in a malignant fashion. Clinical follow up is advised.

This case has been reviewed in intradepartmental consultation by who agree with the above interpretation.

(Electronic Signature)

SPECIMEN SUBMITTED

A: LEFT PHEOCHROMOCYTOMA

B: PERI-ADRENAL SOFT TISSUE

CLINICAL DATA

BENIGN NEOPLASM OF ADRENAL GLAND

GROSS DESCRIPTION

A. Received fresh labeled "left pheochromocytoma" the specimen consists of an ovoid tissue mass with attached fibroadipose tissue measuring 15.0 x 14.5 x 7.6 cm, and weighing 245.7 grams. The mass appears well encapsulated, rubbery, and pink-tan. Cross section reveals a sharply circumscribed tumor mass measuring 14.8 cm in greatest dimensions with a slightly bulging cut surface. Cystic spaces are present and measure up to

[page 2 of 2]
6.9 cm in greatest diameter. Representative sections are submitted in formalin in eight cassettes. Additional tissue with mass and inked line of resection are submitted in cassettes A9-A11.

B. Received fresh labeled "peri-adrenal soft tissue" are multiple irregular yellow-red segments of fibroadipose tissue aggregating to 4.2 x 4.0 x 1.5 cm. Upon sectioning, a fibrous region is identified. Representative sections are submitted in formalin in two cassettes.

Date of Report:
Date of Procedure:
Date of Receipt:
Submitted by:
Location:
Test performed by:

Lab and Collection

SURGICAL PATHOLOGY

Lab and Collection Information

Result History

SURGICAL PATHOLOGY

der Result History Report

Result Information

Result Date and Time

Status

Provider Status

Final result

Reviewed

Status:

This result is currently not released to

Display Full Result Report

Display Order Report

Source: NCI Genomic Data Commons file d378d09e-6962-4cfb-93c0-fcdae1db6350 (TCGA-RT-A6YA.8E4AD039-1F25-4A60-AEA2-E090EAF79C44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).